Somatic mutation profile of tumor specimen C3L-06219-05 (aliquot CPT0425260006) from CPTAC case C3L-06219, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.0 years (24,463 days).
Specimen C3L-06219-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c72a045-c229-4ee6-b7d3-40e6fdfdc556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06219-31 (Blood Derived Normal), aliquot CPT0425370005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d317591-1ac4-4585-b6ba-631dc6a33015

The open-access MAF lists 239 somatic variants for this specimen: 168 protein-altering or splice-affecting, 62 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 62, Intron 5, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 3, In Frame Del 3, 5'UTR 2, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 658/1002 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54066645, COSV54070047; called by muse, mutect2, varscan2
- KLHL3 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469643, CM120724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3805T>G p.L1269V | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV53978035, COSV99687670; called by muse, mutect2, varscan2
- ADIPOQ | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 121/379 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs138773406, CM120073, COSV57859027; called by muse, mutect2, varscan2
- ANKLE2 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs528690169; called by muse, mutect2, varscan2
- BAZ1B | c.4178G>T p.C1393F | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100289894; called by muse, mutect2, varscan2
- C10orf120 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 91/327 reads (28%) | catalogued as rs138012316; called by muse, mutect2, varscan2
- CACNA1B | c.3184C>T p.R1062W | Missense Mutation (SNP) | VAF 174/619 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53122041; called by muse, mutect2, varscan2
- CDAN1 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 274/648 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs752497862, COSV51909487; called by muse, mutect2, varscan2
- CHP1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1381120374; called by muse, mutect2, varscan2
- CHST11 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 173/539 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as COSV57984798; called by muse, mutect2, varscan2
- CNBP | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 128/382 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs775993316; called by muse, mutect2, varscan2
- CSMD3 | c.10829G>T p.G3610V (on ENST00000297405 / NM_001363185.1; = p.G3441V on NM_052900.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV52173741, COSV99832631; called by muse, mutect2, varscan2
- CYFIP1 | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs141966948; called by muse, mutect2, varscan2
- DLC1 | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 121/803 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs1397046892; called by muse, mutect2, varscan2
- DMD | c.4090T>G p.L1364V | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1252905257, COSV63751258; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELAVL2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.841); catalogued as rs753832085, COSV56369285; called by muse, mutect2, varscan2
- EPB41L3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768190757; called by muse, mutect2, varscan2
- FAAH | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 136/443 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200476310; called by muse, mutect2, varscan2
- FAM135B | c.3172T>G p.S1058A | Missense Mutation (SNP) | VAF 144/655 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV52747939; called by muse, mutect2, varscan2
- FAM221A | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs764370088; called by muse, mutect2, varscan2
- FAM234B | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 131/489 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767499682, COSV52194014; called by muse, mutect2, varscan2
- FDFT1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 460/745 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042237; called by muse, mutect2, varscan2
- FSIP2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV58096747; called by muse, mutect2, varscan2
- FSIP2 | c.19234C>T p.P6412S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV58079852; called by muse, mutect2, varscan2
- FSTL5 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100055479, COSV60187156, COSV60193080; called by muse, mutect2, varscan2
- GABRG1 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781246399, COSV54949807, COSV54950182; called by muse, varscan2
- GFRA1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 172/612 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs567690402, COSV100816072, COSV62605811; called by muse, mutect2, varscan2
- GUCY2D | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 159/528 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as CM155804, COSV54699605; called by muse, mutect2, varscan2
- HKDC1 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 158/556 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs760356131; called by muse, mutect2, varscan2
- HSPG2 | c.13106C>T p.P4369L | Missense Mutation (SNP) | VAF 228/734 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs370414671; called by muse, mutect2, varscan2
- IGSF10 | c.4055A>C p.K1352T | Missense Mutation (SNP) | VAF 164/551 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as rs778850625, COSV56789008; called by muse, mutect2, varscan2
- IGSF3 | c.1747C>T p.R583W (on ENST00000369486 / NM_001007237.3; = p.R603W on NM_001542.4) | Missense Mutation (SNP) | VAF 210/721 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs200735353, COSV59592548; ClinVar: uncertain significance; called by muse, varscan2
- IL1B | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as rs1191503899; called by muse, mutect2, varscan2
- JAKMIP3 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 123/459 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53819324; called by muse, mutect2, varscan2
- KCNB2 | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 296/662 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101579045, COSV73049565; called by muse, mutect2, varscan2
- KCNT2 | c.3164T>C p.L1055P | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54061902, COSV54080661; called by muse, mutect2, varscan2
- LRRK2 | c.7146A>C p.K2382N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs919570241, COSV104406139, COSV54145667; called by muse, mutect2, varscan2
- LTB4R2 | c.1037G>A p.R346Q (on ENST00000528054; = p.R315Q on NM_019839.5) | Missense Mutation (SNP) | VAF 247/737 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs761046681, COSV51864506; called by muse, mutect2, varscan2
- MAGEB6B | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69689672; called by muse, mutect2, varscan2
- MAGED1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 133/240 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV100431353; called by muse, mutect2, varscan2
- MARVELD2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 133/653 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs143318841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCM7 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 132/434 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996164; called by muse, mutect2, varscan2
- MDGA1 | c.2224+1G>A p.X742_splice | Splice Site (SNP) | VAF 112/473 reads (24%) | catalogued as rs1173960127, COSV99776896; called by muse, mutect2, varscan2
- MYH9 | c.4973G>A p.R1658H | Missense Mutation (SNP) | VAF 182/600 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs375515914; called by muse, mutect2, varscan2
- NCKAP5 | c.3313T>G p.L1105V | Missense Mutation (SNP) | VAF 136/464 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV58436402, COSV58453778; called by muse, mutect2, varscan2
- NLRP7 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 278/1070 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs771101644, COSV60171092; called by muse, mutect2, varscan2
- NPY2R | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 206/659 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279875; called by muse, mutect2
- NRDE2 | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 163/572 reads (28%) | catalogued as rs1315866944; called by muse, mutect2, varscan2
- NSMAF | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs996993090; called by muse, mutect2, varscan2
- OR10V1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs770628884, COSV55699914; called by muse, mutect2, varscan2
- OR52A5 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs775521911; called by muse, mutect2, varscan2
- OR5T2 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 91/383 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV57588098; called by muse, mutect2, varscan2
- OR8H2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57943415; called by muse, mutect2, varscan2
- PHACTR3 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 106/386 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs199841810, COSV63033377; called by muse, mutect2, varscan2
- PHLDB2 | c.3440G>A p.R1147Q (on ENST00000393925 / NM_001134439.2; = p.R1104Q on NM_145753.2) | Missense Mutation (SNP) | VAF 104/371 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs921553958, COSV67316076; called by muse, mutect2, varscan2
- PKD1L3 | c.1711C>G p.H571D | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1203483137; called by muse, mutect2
- PLCL1 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs771318565, COSV70825214; called by muse, mutect2, varscan2
- PLEKHN1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 152/444 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100647518; called by muse, mutect2, varscan2
- PLPPR2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 151/520 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.508); catalogued as rs145102667; called by muse, mutect2, varscan2
- PPP1R3A | c.1905A>C p.E635D | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99492163; called by muse, mutect2, varscan2
- PRDM5 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53357080; called by muse, mutect2, varscan2
- PROX2 | c.1724C>T p.S575L (on ENST00000556489 / NM_001243007.1; = p.S348L on NM_001080408.2) | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs775024410, COSV71519963; called by muse, mutect2, varscan2
- PRRX1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 219/489 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs747075971, COSV53414416; called by muse, mutect2, varscan2
- PXDN | c.4411T>G p.L1471V | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53228523, COSV53240068, COSV99413689; called by muse, mutect2, varscan2
- PYCR3 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 218/930 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV55307399; called by muse, mutect2, varscan2
- SCN5A | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs575883763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2B3 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 217/695 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1454335466; called by muse, mutect2, varscan2
- SH3RF1 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 141/446 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs753089960, COSV52925591; called by muse, mutect2, varscan2
- SHOX | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 195/657 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as CM020772; called by muse, mutect2, varscan2
- SI | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as rs866800826, COSV52296638; called by muse, mutect2, varscan2
- SLC26A4 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs766602152, COSV55917395; called by muse, mutect2, varscan2
- SPPL2B | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 196/606 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs760548564, COSV66316943; called by muse, mutect2, varscan2
- SULF1 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV52680381; called by muse, mutect2, varscan2
- TENM4 | c.6106G>A p.E2036K | Missense Mutation (SNP) | VAF 142/450 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200508306; called by muse, mutect2, varscan2
- TMCO4 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 236/778 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as rs148804412; called by muse, mutect2, varscan2
- TMEM132B | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 129/416 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs767342934, COSV54749305; called by muse, mutect2, varscan2
- TNN | c.3316G>A p.G1106R | Missense Mutation (SNP) | VAF 209/484 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747972743, COSV99512301; called by muse, mutect2, varscan2
- TRIM71 | c.456C>G p.H152Q | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as rs1034296114; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 72/257 reads (28%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- TUSC3 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- VIM | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs116370722, COSV56406520; called by muse, mutect2, varscan2
- WDR46 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 246/1023 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs777676380; called by muse, mutect2, varscan2
- XDH | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 147/467 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs1178823034; called by muse, mutect2, varscan2
- ZNF254 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV61642805; called by muse, mutect2, varscan2
- ZNF536 | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 243/832 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62834571; called by muse, varscan2
- ACTL9 | c.1000T>G p.L334V | Missense Mutation (SNP) | VAF 224/707 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMBN | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AOX1 | c.3347A>C p.K1116T | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ASCL4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 186/625 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATM | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- C10orf71 | c.554A>C p.N185T | Missense Mutation (SNP) | VAF 142/504 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- C2orf16 | c.4393G>A p.A1465T | Missense Mutation (SNP) | VAF 121/401 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND1 | c.2822_2825del p.E941Vfs*14 | Frame Shift Del (DEL) | VAF 81/320 reads (25%) | called by mutect2, pindel, varscan2
- CDC25C | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- CFTR | c.2162T>G p.M721R | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CHD9 | c.6686A>G p.E2229G | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CKAP5 | c.2642T>A p.L881Q | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNKSR1 | c.1906G>T p.E636* (on ENST00000374253 / NM_001297647.2; = p.E629* on NM_006314.3) | Nonsense Mutation (SNP) | VAF 119/441 reads (27%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, varscan2
- CUBN | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by mutect2, varscan2
- DCC | c.2621A>G p.K874R | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAJC21 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- DOT1L | c.3805_3811delinsTCCG p.Q1269_S1271delinsSA | In Frame Del (DEL) | VAF 152/569 reads (27%) | called by pindel, varscan2*
- DYNC1H1 | c.7413_7418del p.Q2471_N2473delinsH | In Frame Del (DEL) | VAF 122/464 reads (26%) | called by mutect2, pindel, varscan2
- EIF4A2 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPM2A | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 155/590 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FSCB | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GLI3 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLIS3 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 250/836 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.476); called by muse, varscan2
- GSTM5 | c.360+2_360+3del p.X120_splice | Splice Site (DEL) | VAF 50/230 reads (22%) | called by pindel, varscan2
- HLA-G | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 162/740 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- IGSF5 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- IRAK1 | c.850_870del p.Y284_F290del | In Frame Del (DEL) | VAF 87/200 reads (44%) | called by mutect2, varscan2
- KBTBD2 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCTD19 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 125/477 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KIAA2026 | c.5940T>G p.H1980Q | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KIF2C | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP20-4 | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 111/379 reads (29%) | PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- L3MBTL4 | c.240T>G p.H80Q | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MAGEB4 | c.346T>G p.L116V | Missense Mutation (SNP) | VAF 165/278 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEI1 | c.672del p.L226Sfs*22 | Frame Shift Del (DEL) | VAF 94/385 reads (24%) | called by mutect2, pindel, varscan2
- NOM1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 166/622 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- NR4A1 | c.1741T>G p.L581V | Missense Mutation (SNP) | VAF 170/586 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- OPLAH | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 378/839 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR13F1 | c.748T>A p.L250M | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4Q2 | c.683A>C p.K228T | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- OR5T1 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1954A>T p.R652W (on ENST00000259318 / NM_001136562.3; = p.R883W on NM_007203.5) | Missense Mutation (SNP) | VAF 156/582 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDH15 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA8 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 280/925 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PEG3 | c.3479A>T p.E1160V | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PHYHIPL | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PIK3IP1 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R3A | c.2215A>T p.S739C | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PPP2R1A | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 137/427 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKD1 | c.1086A>C p.E362D | Missense Mutation (SNP) | VAF 129/464 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSME4 | c.4418C>G p.A1473G | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RAD54L2 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 154/425 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBFOX1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 196/698 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- RGPD8 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEC61A2 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- SGTA | c.795del p.S266Rfs*26 | Frame Shift Del (DEL) | VAF 129/518 reads (25%) | called by pindel, varscan2
- SKP1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC52A3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 186/535 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPEM3 | c.226T>C p.C76R | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SPEM3 | c.3257C>T p.S1086F | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- STAC | c.1166A>G p.K389R | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- STRN4 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 170/660 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STX8 | c.119T>A p.L40H | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SUDS3 | c.213-2_215del p.X71_splice | Splice Site (DEL) | VAF 22/120 reads (18%) | called by pindel, varscan2
- TEAD2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 181/613 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP63 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 327/774 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM51 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM77 | c.1044A>C p.K348N | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- UNC13A | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- USP8 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VPS54 | c.1337A>G p.Q446R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WASF2 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 138/474 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF17 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF300 | c.1650A>G p.I550M | Missense Mutation (SNP) | VAF 133/455 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF43 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZNF569 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZNF569 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF605 | c.150T>G p.D50E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF701 | c.998A>C p.E333A (on ENST00000301093; = p.E267A on NM_018260.3) | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF837 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 185/618 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ZNF880 | c.424T>G p.L142V | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACAN | c.5985C>T p.S1995= | Silent (SNP) | VAF 142/625 reads (23%) | catalogued as rs753770648; called by muse, mutect2, varscan2
- ACO2 | c.234C>T p.A78= | Silent (SNP) | VAF 182/601 reads (30%) | called by muse, mutect2, varscan2
- AL592490.1 | c.2007A>C p.G669= | Silent (SNP) | VAF 186/379 reads (49%) | catalogued as COSV101308231; called by muse, mutect2, varscan2
- ARHGAP19 | c.943C>A p.R315= | Silent (SNP) | VAF 104/340 reads (31%) | catalogued as COSV100363078; called by muse, mutect2, varscan2
- BACE1 | c.720C>T p.I240= | Silent (SNP) | VAF 107/346 reads (31%) | catalogued as rs753670882; called by muse, mutect2, varscan2
- BAZ2A | c.5526C>T p.T1842= | Silent (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2547C>T p.A849= | Silent (SNP) | VAF 206/625 reads (33%) | catalogued as rs763114939; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLASP1 | c.4164G>A p.T1388= | Silent (SNP) | VAF 98/401 reads (24%) | catalogued as rs760703210; called by muse, mutect2, varscan2
- CLEC3B | c.501C>T p.G167= | Silent (SNP) | VAF 205/716 reads (29%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1569C>A p.G523= | Silent (SNP) | VAF 128/448 reads (29%) | called by muse, varscan2
- CPLANE1 | c.8430C>G p.V2810= | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- CRMP1 | c.204A>G p.G68= | Silent (SNP) | VAF 127/458 reads (28%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1107C>T p.S369= | Silent (SNP) | VAF 94/392 reads (24%) | catalogued as rs770673636; called by muse, mutect2, varscan2
- DMXL1 | c.763C>T p.L255= | Silent (SNP) | VAF 19/65 reads (29%) | called by mutect2, varscan2
- DNAH11 | c.1443T>G p.T481= | Silent (SNP) | VAF 41/147 reads (28%) | called by muse, mutect2, varscan2
- DOCK4 | c.4611G>T p.G1537= | Silent (SNP) | VAF 55/340 reads (16%) | called by muse, mutect2, varscan2
- DOT1L | c.1893G>A p.S631= | Silent (SNP) | VAF 111/350 reads (32%) | catalogued as rs776193277; called by muse, mutect2, varscan2
- EFCAB6 | c.1135A>C p.R379= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- ELK1 | c.372G>A p.G124= | Silent (SNP) | VAF 234/424 reads (55%) | called by muse, mutect2, varscan2
- EXD3 | c.1860C>T p.G620= | Silent (SNP) | VAF 141/460 reads (31%) | catalogued as rs762239994; called by muse, mutect2, varscan2
- FNDC1 | c.1077T>C p.P359= | Silent (SNP) | VAF 93/291 reads (32%) | called by muse, mutect2, varscan2
- GABRE | c.42G>A p.L14= | Silent (SNP) | VAF 153/257 reads (60%) | called by muse, mutect2, varscan2
- GLI2 | c.1755C>T p.D585= (on ENST00000361492 / NM_001374353.1; = p.D602= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 231/803 reads (29%) | catalogued as rs139202322; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR87 | c.606A>G p.K202= | Silent (SNP) | VAF 157/537 reads (29%) | called by muse, mutect2, varscan2
- IGF2 | c.312C>T p.R104= (on ENST00000434045 / NM_001127598.3; = p.R48= on NM_000612.6) | Silent (SNP) | VAF 120/403 reads (30%) | catalogued as rs754399358, COSV56097275; called by muse, mutect2, varscan2
- ITGA9 | c.1209C>T p.A403= | Silent (SNP) | VAF 91/362 reads (25%) | catalogued as rs781497892, COSV99292190; called by muse, mutect2, varscan2
- KAT6A | c.4797C>G p.T1599= | Silent (SNP) | VAF 167/520 reads (32%) | called by muse, mutect2, varscan2
- LRRTM1 | c.309C>T p.S103= | Silent (SNP) | VAF 154/526 reads (29%) | catalogued as COSV54437701, COSV54440210; called by muse, mutect2, varscan2
- MAGEB5 | c.289T>C p.L97= | Silent (SNP) | VAF 94/218 reads (43%) | catalogued as COSV66868829; called by muse, mutect2, varscan2
- MAP2 | c.4830T>C p.S1610= | Silent (SNP) | VAF 152/554 reads (27%) | catalogued as COSV52284688, COSV52309260, COSV99561686; called by muse, mutect2, varscan2
- NETO1 | c.333T>C p.S111= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV100199351; called by muse, mutect2, varscan2
- NPTX2 | c.243C>T p.R81= | Silent (SNP) | VAF 273/815 reads (33%) | catalogued as COSV99674750; called by muse, mutect2, varscan2
- OBSCN | c.13179C>T p.N4393= | Silent (SNP) | VAF 199/875 reads (23%) | catalogued as rs771435993, COSV52810396; called by muse, mutect2, varscan2
- OR13A1 | c.591C>T p.C197= | Silent (SNP) | VAF 202/659 reads (31%) | catalogued as rs147583204; called by muse, varscan2
- OR2B3 | c.540G>A p.E180= | Silent (SNP) | VAF 182/782 reads (23%) | called by muse, mutect2, varscan2
- OR6N2 | c.474T>A p.S158= | Silent (SNP) | VAF 103/500 reads (21%) | catalogued as COSV59410628, COSV59411893; called by muse, mutect2, varscan2
- PAX1 | c.975C>T p.G325= | Silent (SNP) | VAF 184/615 reads (30%) | catalogued as rs777132194; called by muse, mutect2, varscan2
- PCDH11Y | c.873A>G p.P291= (on ENST00000400457 / NM_032973.2; = p.P280= on NM_032971.3) | Silent (SNP) | VAF 90/186 reads (48%) | called by muse, mutect2, varscan2
- PCDH9 | c.3714A>G p.*1238= (on ENST00000377865 / NM_203487.3; = p.*1204= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/269 reads (21%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2, varscan2
- PHRF1 | c.3876C>T p.P1292= (on ENST00000264555 / NM_001286581.2; = p.P1291= on NM_020901.4) | Silent (SNP) | VAF 247/821 reads (30%) | catalogued as rs752615310; called by muse, mutect2, varscan2
- PIP4K2A | c.831G>A p.L277= | Silent (SNP) | VAF 108/378 reads (29%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.732G>A p.Q244= | Silent (SNP) | VAF 128/456 reads (28%) | catalogued as COSV100490621; called by muse, mutect2, varscan2
- PNMA8B | c.996C>T p.F332= | Silent (SNP) | VAF 167/603 reads (28%) | catalogued as COSV66536002; called by muse, mutect2, varscan2
- PRIM1 | c.1101A>G p.K367= | Silent (SNP) | VAF 93/236 reads (39%) | catalogued as rs1477023646; called by muse, mutect2, varscan2
- RAPGEF4 | c.2181T>C p.D727= | Silent (SNP) | VAF 78/238 reads (33%) | catalogued as rs1282869751; called by muse, mutect2, varscan2
- RBM12 | c.264G>A p.R88= | Silent (SNP) | VAF 97/346 reads (28%) | catalogued as rs767562243; called by muse, mutect2
- ROBO1 | c.3582T>G p.P1194= | Silent (SNP) | VAF 112/334 reads (34%) | catalogued as COSV71391666; called by muse, mutect2, varscan2
- SNRNP200 | c.3417A>T p.V1139= | Silent (SNP) | VAF 131/414 reads (32%) | called by muse, mutect2, varscan2
- SP1 | c.1338T>G p.S446= (on ENST00000327443 / NM_138473.3; = p.S439= on NM_003109.1) | Silent (SNP) | VAF 160/554 reads (29%) | called by muse, mutect2, varscan2
- SYT6 | c.150C>T p.S50= | Silent (SNP) | VAF 126/446 reads (28%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1062T>C p.C354= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- TOMM6 | c.162G>T p.A54= | Silent (SNP) | VAF 91/416 reads (22%) | catalogued as COSV59253286; called by muse, mutect2, varscan2
- TPO | c.2676C>T p.P892= | Silent (SNP) | VAF 169/589 reads (29%) | catalogued as COSV61095895, COSV61101044; called by muse, mutect2, varscan2
- TSPY8 | c.84C>A p.A28= | Silent (SNP) | VAF 174/791 reads (22%) | called by muse, mutect2, varscan2
- VCAN | c.2895T>G p.T965= | Silent (SNP) | VAF 78/288 reads (27%) | catalogued as rs141161041; called by muse, mutect2, varscan2
- WSCD2 | c.594G>A p.E198= | Silent (SNP) | VAF 180/623 reads (29%) | catalogued as COSV54582310; called by muse, varscan2
- ZBTB46 | c.201G>A p.S67= | Silent (SNP) | VAF 140/512 reads (27%) | catalogued as rs567479339; called by muse, mutect2, varscan2
- ZEB2 | c.2550T>G p.S850= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as COSV57956914; called by muse, mutect2, varscan2
- ZFHX4 | c.7752T>C p.D2584= | Silent (SNP) | VAF 106/567 reads (19%) | called by muse, mutect2, varscan2
- ZNF318 | c.4470C>T p.F1490= | Silent (SNP) | VAF 348/726 reads (48%) | catalogued as rs552813375, COSV58934515; called by muse, varscan2
- ZNF529 | c.1095T>A p.P365= | Silent (SNP) | VAF 85/291 reads (29%) | called by muse, mutect2, varscan2
- ZNRF4 | c.957C>T p.G319= | Silent (SNP) | VAF 178/595 reads (30%) | catalogued as rs1330866467, COSV55772998; called by muse, mutect2, varscan2
- C4orf50 | c.-820C>T | 5'UTR (SNP) | VAF 111/496 reads (22%) | catalogued as rs771845184, COSV100135814; called by muse, varscan2
- GCNT2 | c.925+27007A>T | Intron (SNP) | VAF 202/443 reads (46%) | called by muse, mutect2, varscan2
- PRM2 | c.*217G>A | 3'UTR (SNP) | VAF 151/504 reads (30%) | called by muse, mutect2, varscan2
- SLC25A3 | c.282+222T>C | Intron (SNP) | VAF 107/374 reads (29%) | called by muse, mutect2, varscan2
- TASOR2 | c.-563C>T | 5'UTR (SNP) | VAF 83/598 reads (14%) | called by muse, mutect2, varscan2
- THSD4 | c.-80+15078G>A | Intron (SNP) | VAF 362/814 reads (44%) | catalogued as rs760880783; called by muse, mutect2, varscan2
- TTN | c.10360+5561A>G | Intron (SNP) | VAF 98/327 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+1410T>C | Intron (SNP) | VAF 99/300 reads (33%) | called by muse, mutect2, varscan2
- WNK2 | chr9:93318483 G>A | 3'Flank (SNP) | VAF 119/494 reads (24%) | catalogued as rs200539322, COSV52939289; called by muse, mutect2, varscan2
